Gene-level copy-number profile of tumor specimen C3N-02281-02 (profiled together with C3N-02281-03) from CPTAC case C3N-02281, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 63.5 years (23,197 days).
Specimen C3N-02281-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ab0ce26f-dcea-4f22-a477-6b35880483c3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02281-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/b1774348-3bb6-4b5f-9e27-66d7dffb0005

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 7,953; copy number 2: 25,280; copy number 3: 17,162; copy number 4: 5,713; copy number 5: 1,908; copy number 6: 159; copy number 7: 40; copy number 8: 93; copy number 9: 92.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:121,873,089–122,062,036, 1 gene: PTPRZ1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,275 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–2,817,767, 178 genes, copy number 5 (broad region; genes not listed).
- chr1:8,292,157–8,848,921, 7 genes, copy number 6 (within-gene range 3–6): RNU6-991P, SLC45A1, Y_RNA, RERE, RERE-AS1, AL096855.1, AL096855.2.
- chr1:14,338,825–14,419,973, 1 gene, copy number 7: KAZN-AS1.
- chr1:15,617,458–16,657,232, 53 genes, copy number 5 (within-gene range 3–5): DDI2, RSC1A1, AL121992.2, PLEKHM2, AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82, FBLIM1, RPL12P14, UQCRHL, AL450998.1, FLJ37453, SPEN, AL034555.1, ZBTB17, AL355994.4, AL355994.1, AL355994.5, TBC1D3P6, SRARP, AL355994.3, HSPB7, CLCNKA, AL355994.2, CLCNKB, FAM131C, EPHA2, AL451042.2, AL451042.1, ARHGEF19-AS1, ARHGEF19, ANO7L1, CPLANE2, MT1XP1, FBXO42, SZRD1, RPL22P3, SPATA21, NECAP2, LINC01772, CROCCP3, RNU1-1, AL137802.2, AL137802.3, AL137802.1, LINC01783, RNU1-6P, AL355149.1, NBPF1, AL137798.1, CROCCP2, AL137798.3.
- chr1:18,385,829–18,956,676, 10 genes, copy number 7: AL591896.1, KLHDC7A, DYNLL1P3, AL031737.1, PAX7, TAS1R2, ALDH4A1, MIR4695, MIR1290, IFFO2.
- chr1:20,664,014–21,783,606, 26 genes, copy number 7 (within-gene range 1–7): KIF17, AL663074.2, SH2D5, AL663074.1, HP1BP3, EIF4G3, RNU7-200P, MIR1256, RPS15AP6, AL627311.1, HSPE1P27, ECE1, AL031005.1, ECE1-AS1, PPP1R11P1, AL592309.1, AL592309.2, NBPF2P, HS6ST1P1, CROCCP5, NBPF3, PFN1P10, ALPL, LINC02596, RAP1GAP, USP48.
- chr1:69,567,922–70,151,945, 1 gene, copy number 5 (within-gene range 3–9): LRRC7.
- chr1:69,706,950–72,753,772, 32 genes, copy number 5–9 (within-gene range 1–9): AL117353.1, RN7SL538P, PIN1P1, LRRC7-AS1, LRRC40, RN7SL242P, SRSF11, AL353771.1, ANKRD13C, HHLA3, HHLA3-AS1, CTH, Metazoa_SRP, AL354872.1, CHORDC1P5, CASP3P1, LINC01788, AL513285.1, PTGER3, AL031429.1, AL031429.2, ZRANB2-AS1, ZRANB2, MIR186, ZRANB2-AS2, AL358453.1, NEGR1, AL354949.1, AL359821.1, NEGR1-IT1, GDI2P2, AL513166.1.
- chr1:72,636,547–73,355,253, 8 genes, copy number 8: AL583808.1, RNU6-1246P, LINC02796, LINC02797, AL732618.1, KRT8P21, RN7SKP19, LINC01360.
- chr2:61,803,143–63,046,487, 29 genes, copy number 5–6 (within-gene range 3–6): RPS24P7, AC108039.2, FAM161A, RPL31P30, AC107081.2, CCT4, AC107081.1, AC107081.3, COMMD1, Y_RNA, AC018462.1, RPSAP26, AC018462.2, B3GNT2, MIR5192, RN7SL51P, AC093159.2, AC093159.1, RN7SL18P, TMEM17, RPL37P13, RPL21P37, AC092155.1, PSAT1P2, RSL24D1P2, EHBP1, Y_RNA, AC092567.2, AC092567.1.
- chr2:62,957,326–63,048,640, 1 gene, copy number 6 (within-gene range 3–6): AC007098.1.
- chr2:70,887,871–75,728,123, 140 genes, copy number 5–6 (broad region; genes not listed).
- chr3:79,957,566–81,297,345, 9 genes, copy number 5: HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1.
- chr5:58,198–45,895,970, 679 genes, copy number 5 (broad region; genes not listed).
- chr5:179,455,415–180,740,099, 51 genes, copy number 6: AC136628.1, U4, AC136628.4, AC136628.2, AC136628.3, RUFY1, PRDX2P3, RUFY1-AS1, HNRNPH1, Metazoa_SRP, C5orf60, AC136604.1, AC136604.2, CBY3, CANX, HMGB3P22, MAML1, LTC4S, MGAT4B, MIR1229, SQSTM1, MRNIP, RN7SKP150, Y_RNA, AC008393.1, TBC1D9B, RNF130, RPS15AP18, AC010285.2, AC010285.1, AC010285.3, MIR340, AC122713.2, AC122713.1, RASGEF1C, AC104115.1, MAPK9, AC104115.2, AC008610.1, GFPT2, AC034213.1, RNU6-525P, CNOT6, AC122714.1, SCGB3A1, FLT4, AC122714.2, LINC02222, OR2AI1P, RNU1-17P, OR2Y1.
- chr7:3,083,252–8,344,516, 122 genes, copy number 5–9 (broad region; genes not listed).
- chr7:12,330,885–15,068,651, 26 genes, copy number 8: VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26, AC006150.1, GTF3AP5, AC006458.1.
- chr7:16,087,525–19,002,416, 37 genes, copy number 8 (within-gene range 4–8): CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1, HDAC9, MIR1302-6, AC010082.1, RN7SKP266.
- chr7:19,695,461–20,590,085, 16 genes, copy number 7–8: POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1, EEF1A1P27, AC002486.2.
- chr7:33,793,167–35,038,271, 14 genes, copy number 6: AC008080.4, AC008080.3, BMPER, AC007350.1, AC009262.1, RNU6-438P, NPSR1-AS1, NPSR1, RPL7P31, NCAPD2P1, RN7SL132P, AC004788.1, DPY19L1, MIR548N.
- chr8:99,873,200–102,504,137, 71 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr10:14,061–38,783,108, 645 genes, copy number 5 (broad region; genes not listed).
- chr10:102,461,395–105,687,051, 75 genes, copy number 5 (broad region; genes not listed).
- chr10:116,849,499–118,755,249, 30 genes, copy number 5: ENO4, SHTN1, AC023283.1, AC012308.1, VAX1, MIR3663HG, MIR3663, RPL12P26, KCNK18, AL731557.1, SLC18A2, AL391988.1, PDZD8, AC005871.2, EMX2OS, EMX2, AC005871.1, LINC02674, AL513324.1, RAB11FIP2, AC022395.1, CASC2, AL354863.1, FAM204A, LINC00867, SLC25A18P1, PRLHR, TOMM22P5, CACUL1, AL139407.1.
- chr10:118,872,054–118,872,602, 1 gene, copy number 5: RPL17P36.
- chr21:39,556,442–40,864,473, 13 genes, copy number 5: B3GALT5, B3GALT5-AS1, AF064860.1, AF064860.2, IGSF5, PCP4, DSCAM, MIR4760, DSCAM-AS1, AF064863.1, DSCAM-IT1, AF064866.1, YRDCP3.

Autosomal genes at a single copy (total copy number 1): 7,037. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
